Somatic mutation profile of tumor specimen MMRF_1542_1_BM_CD138pos (aliquot MMRF_1542_1_BM_CD138pos_T1_KBS5U_L03498) from MMRF case MMRF_1542, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.3 years (26,395 days).
Specimen MMRF_1542_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f23028e-a817-4732-aab0-a4c76e243da8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1542_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1542_1_PB_CD3pos_C2_KBS5U_L03502; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fcec472-ca6d-47c3-abf2-63dd7165a15f

The open-access MAF lists 31 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 11, Missense Mutation 7, Silent 3, Splice Site 2, 5'UTR 2, 5'Flank 1, Splice Region 1, RNA 1, 3'Flank 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR1 | c.6362G>A p.R2121H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as rs765148329; called by muse, mutect2, varscan2
- DONSON | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as rs753740715, COSV51677039; called by muse, mutect2, varscan2
- HTR1F | c.235T>A p.F79I | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV100138161; called by muse, mutect2
- BANK1 | c.1985A>C p.E662A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- CSMD1 | c.10044T>C p.V3348= (on ENST00000520002; = p.V3347= on NM_033225.6) | Splice Region (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- ERMARD | c.417+1G>C p.X139_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- ITPR2 | c.5150C>T p.S1717L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA4 | c.4501A>G p.T1501A (on ENST00000230538 / NM_001105206.3; = p.T1494A on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDGFC | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SCIN | c.200-2A>G p.X67_splice | Splice Site (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- TRMT2B | c.469A>C p.T157P | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); called by mutect2, varscan2
- ADRB2 | c.744G>A p.V248= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs1004071882; called by muse, mutect2
- IGKV4-1 | c.30T>G p.S10= | Silent (SNP) | VAF 14/14 reads (100%) | called by mutect2, varscan2
- MYH2 | c.3394C>A p.R1132= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV55431734; called by mutect2, varscan2
- AMPD2 | chr1:109619858 G>A | 5'Flank (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56650642; called by muse, mutect2, varscan2
- CLDN1 | c.*432T>A | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by mutect2, varscan2
- CRACR2A | c.*516C>T | 3'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- DBNL | c.*5341C>T | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by mutect2, varscan2
- DIRAS2 | c.*915G>T | 3'UTR (SNP) | VAF 18/68 reads (26%) | catalogued as rs1418327441; called by muse, mutect2, varscan2
- ENTPD5 | c.*2974T>C | 3'UTR (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- EXT1 | c.*1600T>A | 3'UTR (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- FAM83C | c.-49C>T | 5'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as rs1388594250; called by muse, mutect2
- FIGN | c.*4422del | 3'UTR (DEL) | VAF 6/48 reads (13%) | called by pindel, varscan2
- FOXP1 | c.*3531G>C | 3'UTR (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- IL4R | c.*428G>T | 3'UTR (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- KCNJ18 | c.*295C>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs1183689506; called by muse, mutect2
- MIR4290 | n.28G>T | RNA (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- NRXN3 | chr14:79864412 T>C | 3'Flank (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- SERPINA6 | c.613+15C>A | Intron (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- STON1 | c.*225C>T | 3'UTR (SNP) | VAF 24/76 reads (32%) | catalogued as rs1330782129; called by muse, mutect2, varscan2
- ZNF570 | c.-194G>A | 5'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
